TCGA case TCGA-YJ-A8SW — Prostate Adenocarcinoma (TCGA-PRAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Prostate gland; Tissue source site: Stanford University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/74de01bd-30d9-45fc-841d-ed1c0d7446ba

Demographics
Sex at birth: male; Country of residence at enrollment: United States; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Mucinous adenocarcinoma: ICD-O-3 morphology code: 8480/3; ICD-10 code: C61.9; Tissue or organ of origin: Prostate gland; Site of resection or biopsy: Prostate gland; Laterality: Right; Classification of tumor: primary; Year of diagnosis: 2008; Method of diagnosis: Core Biopsy; AJCC clinical T: T1c; AJCC pathologic T: T3b; AJCC pathologic N: N0; Primary gleason grade: Pattern 5; Secondary gleason grade: Pattern 4; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Gleason score: 9.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 2.

Follow-up (1 entry)
- Days to follow up: 148 days; Progression or recurrence: Yes; Progression or recurrence type: Biochemical; Days to recurrence: 148 days.

Molecular and laboratory tests
- Prostate-Specific Antigen (PSA): 0.38 ng/mL (day 148).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-YJ-A8SW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 1,000 mg.
  Slide TCGA-YJ-A8SW-01A-01-TSA: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 70; Percent normal cells: 5; Percent necrosis: 5; Percent stromal cells: 25; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-YJ-A8SW-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Prostate; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Histologic diagnosis: Prostate Adenocarcinoma, Other Subtype; Histologic diagnosis other: adenocarcinoma with focal mucinous features; Method initial path diagnosis: Core needle biopsy; Lymph nodes examined: Yes; Biochemical recurrence indicator: Yes.
- Stage record, Psa: PSA most recent results: 0.38.
- Stage record, Gleason grading: Gleason pattern primary: 5; Gleason pattern secondary: 4.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 148 days; disease-specific survival: no event (censored), 148 days; progression-free interval: no event (censored), 148 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-YJ-A8SW-01A-11D-A376-01): tumor purity 0.83, ploidy 2.4, whole-genome doublings 0.
